Somatic mutation profile of tumor specimen TARGET-20-PASPTW-09A (aliquot TARGET-20-PASPTW-09A-02D) from TARGET case TARGET-20-PASPTW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,516 days).
Specimen TARGET-20-PASPTW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3025a1f4-34f0-468b-a2f7-aae33e3a50b6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASPTW-14A (Bone Marrow Normal), aliquot TARGET-20-PASPTW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5fdd566-9d22-4979-9834-fc93ca5b3532

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT2 | c.12643G>A p.V4215M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs779921101, COSV55812648; called by muse, mutect2, varscan2
- KIT | c.1255_1257del p.D419del | In Frame Del (DEL) | VAF 34/150 reads (23%) | called by pindel, varscan2
- PPP1R14B | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TAF1 | c.4320T>A p.N1440K (on ENST00000373790 / NM_138923.4; = p.N1461K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
